TCGA case TCGA-US-A77G — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: Garvan Institute of Medical Research. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/74aa6675-28b7-46dc-9015-f07a07c7b018

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 64 years; Vital status: Dead; Days to death: 12 days; Cause of death: Surgical Complications; Cause of death source: Medical Record.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 64.2 years (23,443 days); Year of diagnosis: 2010; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Pancreas Head; Tumor grade category: Four Tier.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 11; Tumor largest dimension diameter: 2 cm.
   Treatment given: Treatment type: Whipple.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 12 days; Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.
- Alcohol history: Yes; Alcohol intensity: Heavy Drinker; Alcohol drinks per day: 3; Alcohol days per week: 7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-US-A77G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 150 mg.
  Slide TCGA-US-A77G-01A-01-TSA: Section location: Top; Percent tumor cells: 8; Percent tumor nuclei: 12; Percent normal cells: 45; Percent necrosis: 2; Percent stromal cells: 45; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-US-A77G-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-US-A77G-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 200 mg.
  Slide TCGA-US-A77G-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 85; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Tumor status: Tumor free; Tobacco smoking history indicator: 1; Alcohol exposure intensity: Daily Drinker; Alcohol consumption frequency: 7; Diabetes diagnosis indicator: No; History chronic pancreatitis: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 12 days; disease-specific survival: no event (censored), 12 days; progression-free interval: no event (censored), 12 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-US-A77G-01A-11D-A32M-01): tumor purity 0.43, ploidy 1.87, whole-genome doublings 0.
